Gene-level copy-number profile of tumor specimen TCGA-EJ-5524-01A from TCGA case TCGA-EJ-5524, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 57.1 years (20,854 days).
Specimen TCGA-EJ-5524-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.7090ffdb-b670-4d60-a06f-b3ecc644c84a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EJ-5524-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/852da09c-f993-4cf7-a7d3-61d0e3136621

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 37; copy number 1: 7,633; copy number 2: 51,873; copy number 3: 275.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EJ-5524-01A-01D-1574-01): tumor purity 0.61, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:22,544,986–23,115,536, 24 genes (within-gene range 0–1): SORBS3, AC037459.4, AC037459.3, PDLIM2, AC037459.1, C8orf58, CCAR2, AC037459.2, BIN3, AC105046.1, EGR3, AC055854.1, AC105046.2, PEBP4, AC037441.1, AC037441.2, RN7SL303P, AC107959.1, RHOBTB2, TNFRSF10B, AC107959.2, AC107959.3, AC107959.4, AC107959.5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 5,260. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
